Surgical pathology report (de-identified scan), TCGA case TCGA-B2-A4SR, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-A4SR-01A (Primary Tumor).

Final Surgical Pathology Report

Procedure:

Diagnosis

Kidney, right, nephrectomy: Renal cell carcinoma, conventional (clear cell) type, size 7.5 cm in greatest dimension (superior pole), with vascular invasion.

Microscopic Description:

Histologic type: Renal cell carcinoma, conventional (clear cell) type
Histologic grade (Fuhrman Nuclear Grade): 4 (Although much of the tumor is grade 2, there are several areas of grade 4 nuclei present).
Primary tumor (pT): Tumor is 7.5 cm in greatest dimension (pT2a)
Margins of resection: Negative
Regional lymph nodes (pN): None submitted
Vascular invasion: Present
Non-neoplastic kidney: Unremarkable.
Additional findings: Tumor necrosis.

Specimen

Right kidney

Clinical Information

Renal mass

100-0-3

carcinoma, clear cell 8310/3

Site: Kidney, NO 6649

hw
10/26/12

Gross Description

Received fresh for tissue procurement labeled "right kidney" is a 717 g, 13.5 x 8.0 x 7.5 cm right kidney with attached, probe-patent 5.5 cm ureter and a moderate amount of perinephric fat. The renal capsule is delicate tan-pink. The specimen is bivalved to reveal a 7.5 x 6.5 x 5.0 cm focally cystic pale tan to yellow orange tumor mass superiorly. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The tumor is present within 0.3 cm of the inked surface of the specimen. The renal pelvis is smooth glistening tan white. The remaining parenchyma is homogenous pale tan red-brown with a well-defined corticomedullary junction and a maximal cortical thickness of 1.3 cm. No additional mass lesion or abnormality is identified.

Summary: 1 - vascular and ureteral margins, 2 and 3 - tumor to inked surface of specimen, 4 through 7 - tumor 8 - tumor to normal, 9 - renal pelvis, 10 and 11 - random normal

	Yes	No
Cellular atypia		
Dissected specimen		
Primary site discrepancy		
History discrepancy		
Pathology discrepancy		
Discrepancy noted		
UNQUALIFIED		

hw
10/26/12

Source: NCI Genomic Data Commons file 6990828c-d4f1-45a1-8ed5-c9e120c84ac9 (TCGA-B2-A4SR.E59F60B8-34CD-4E5D-A960-82392A66C136.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).